Surgical pathology report (de-identified scan), TCGA case TCGA-58-8387, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-8387-01A (Primary Tumor).

[REDACTED]

[REDACTED]

[REDACTED]

Pathology Report-Summary:

Material:

Lung, right, lower lobe: 14.0 x 12.0 x 7.5 cm

Tumor: 6.0 x 4.0 x 4.2 cm

Diagnosis:

Squamous Cell Carcinoma (NOS)

pT2b, pN0 (0/31), pMx, G3

[REDACTED]

[REDACTED]

Date:

Source: NCI Genomic Data Commons file 260f477a-898e-4b77-be0e-8cc0ad97e99c (TCGA-58-8387.F60B853B-5D1D-47CC-A961-DB2DA5AA837B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).